CCDI case PBCLLF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/77bb2abe-4f72-4679-8f9b-4d39dcb02c1c

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 23.6 years (8,628 days).

Biospecimens (3 samples)
- Sample 0DUKGV: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUKHC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DUKIX: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
